Somatic mutation profile of tumor specimen C3L-00136-03 (aliquot CPT0000730008) from CPTAC case C3L-00136, project CPTAC-3 (Uterus, NOS — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Uterus, NOS; AJCC pathologic stage: Stage I; FIGO stage: Stage I; Tumor grade: G1; Age at diagnosis: 50.7 years (18,533 days).
Specimen C3L-00136-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8bf5e8e7-ba9b-463c-b1a8-538d1d4a4d0f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-00136-31 (Blood Derived Normal), aliquot CPT0003860002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/96b2c337-1043-4f65-8ef1-82eb775664e6

The open-access MAF lists 54 somatic variants for this specimen: 38 protein-altering or splice-affecting, 14 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 27, Silent 14, Splice Site 4, Nonsense Mutation 2, Intron 2, Frame Shift Del 2, In Frame Del 1, Frame Shift Ins 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCG8 | c.1234C>T p.R412* | Nonsense Mutation (SNP) | VAF 68/328 reads (21%) | catalogued as rs137852991, CM003583, COSV55395411; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CDH1 | c.1901C>T p.A634V | Missense Mutation (SNP) | VAF 86/312 reads (28%) | SIFT tolerated (0.2); PolyPhen benign (0.019); catalogued as rs121964878, CM034217, COSV55730231; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- CTNNB1 | c.98C>A p.S33Y | Missense Mutation (SNP) | VAF 84/280 reads (30%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121913400, COSV62687839, COSV62688300, COSV62688644; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- PTEN | c.203A>G p.Y68C | Missense Mutation (SNP) | VAF 15/58 reads (26%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs876660634, CM094222, COSV64293993; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PTEN | c.388C>G p.R130G | Missense Mutation (SNP) | VAF 125/289 reads (43%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121909224, CM094223, CM971273, COSV64288384, COSV64288463, COSV64297940, COSV64311187; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ANTKMT | c.661C>T p.P221S | Missense Mutation (SNP) | VAF 46/117 reads (39%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.005); catalogued as rs771745454; called by muse, mutect2, varscan2
- B3GNT7 | c.317C>T p.P106L | Missense Mutation (SNP) | VAF 38/187 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.866); catalogued as rs769041298; called by muse, mutect2, varscan2
- C10orf90 | c.436C>T p.R146C | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs760735148, COSV52950749; called by muse, mutect2, varscan2
- CCDC71 | c.62C>T p.T21M | Missense Mutation (SNP) | VAF 50/131 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs772229174, COSV58909785; called by muse, mutect2, varscan2
- CDH19 | c.367G>A p.A123T | Missense Mutation (SNP) | VAF 64/235 reads (27%) | SIFT tolerated (0.93); PolyPhen benign (0); catalogued as rs141432968, COSV50956344; called by muse, mutect2, varscan2
- COL5A3 | c.1848G>A p.P616= | Splice Region (SNP) | VAF 27/87 reads (31%) | catalogued as rs752232759, COSV53419622; called by muse, mutect2, varscan2
- CPNE6 | c.454G>A p.D152N | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.484); catalogued as rs539888917, COSV53745064; called by muse, varscan2
- CUX1 | c.1294_1296del p.S432del | In Frame Del (DEL) | VAF 17/65 reads (26%) | catalogued as rs781978724; called by mutect2, pindel
- DTYMK | c.226C>T p.R76C | Missense Mutation (SNP) | VAF 37/136 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59871247; called by muse, mutect2, varscan2
- IGHM | c.521C>T p.T174M | Missense Mutation (SNP) | VAF 178/558 reads (32%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.895); catalogued as rs540744199; called by muse, mutect2, varscan2
- KMT2C | c.328C>T p.R110* | Nonsense Mutation (SNP) | VAF 37/183 reads (20%) | catalogued as COSV51440123; called by muse, mutect2, varscan2
- MRAS | c.385G>T p.D129Y | Missense Mutation (SNP) | VAF 61/220 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56671807; called by muse, mutect2, varscan2
- RASAL3 | c.1388C>T p.A463V | Missense Mutation (SNP) | VAF 20/51 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.238); catalogued as rs765698882; called by muse, mutect2, varscan2
- RPA1 | c.1376C>T p.P459L | Missense Mutation (SNP) | VAF 24/67 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.203); catalogued as rs141166851; called by muse, mutect2, varscan2
- SIRT2 | c.94G>A p.A32T | Missense Mutation (SNP) | VAF 29/126 reads (23%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as rs926292218, COSV50874936; called by muse, mutect2, varscan2
- SPATA5 | c.505+1G>A p.X169_splice | Splice Site (SNP) | VAF 14/33 reads (42%) | catalogued as rs762714956; called by muse, mutect2, varscan2
- TAF1 | c.3482G>T p.R1161L (on ENST00000373790 / NM_138923.4; = p.R1182L on NM_004606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/308 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV52111361, COSV99335726; called by muse, mutect2
- WDR86 | c.1013G>A p.R338H | Missense Mutation (SNP) | VAF 41/99 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs1242661285; called by muse, mutect2, varscan2
- ANKFN1 | c.1067del p.G356Dfs*68 | Frame Shift Del (DEL) | VAF 35/123 reads (28%) | called by mutect2, pindel, varscan2
- CCDC102A | c.376C>T p.R126C | Missense Mutation (SNP) | VAF 18/40 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CEP95 | c.857G>A p.S286N | Missense Mutation (SNP) | VAF 50/132 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CPNE5 | c.142G>C p.V48L | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.92); called by muse, mutect2, varscan2
- ECT2 | c.1068+2T>C p.X356_splice (on ENST00000392692 / NM_001349098.2; = p.X325_splice on NM_018098.6 and 2 other RefSeq transcripts) | Splice Site (SNP) | VAF 13/49 reads (27%) | called by muse, mutect2, varscan2
- FBXW7 | c.1629_1630del p.R543Sfs*7 (on ENST00000281708 / NM_001349798.2; = p.R463Sfs*7 on NM_018315.5) | Frame Shift Del (DEL) | VAF 32/117 reads (27%) | called by pindel, varscan2
- FNBP1L | c.1411T>A p.W471R (on ENST00000271234 / NM_001164473.2; = p.W413R on NM_017737.5) | Missense Mutation (SNP) | VAF 28/82 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- GIT1 | c.186+2T>C p.X62_splice | Splice Site (SNP) | VAF 30/88 reads (34%) | called by muse, varscan2
- IARS2 | c.2071T>G p.Y691D | Missense Mutation (SNP) | VAF 39/245 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- IGHA1 | c.78C>G p.C26W | Missense Mutation (SNP) | VAF 52/176 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LRFN4 | c.1405_1408dup p.Y470* | Frame Shift Ins (INS) | VAF 36/167 reads (22%) | called by mutect2, pindel, varscan2
- OR11H2 | c.11C>T p.S4F (on ENST00000556246; = p.S15F on NM_001197287.1) | Missense Mutation (SNP) | VAF 81/282 reads (29%) | SIFT deleterious (0.05); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- PCCA | c.1746+2T>A p.X582_splice | Splice Site (SNP) | VAF 24/80 reads (30%) | called by muse, mutect2, varscan2
- SHROOM3 | c.3328G>A p.G1110R | Missense Mutation (SNP) | VAF 176/475 reads (37%) | SIFT tolerated (0.05); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- TLN2 | c.2806G>A p.A936T | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- AJAP1 | c.477G>T p.L159= | Silent (SNP) | VAF 5/21 reads (24%) | called by muse, mutect2, varscan2
- CRLF1 | c.597G>A p.K199= | Silent (SNP) | VAF 73/216 reads (34%) | called by muse, mutect2, varscan2
- ELFN2 | c.39C>T p.C13= | Silent (SNP) | VAF 41/129 reads (32%) | catalogued as rs746804136, COSV101297652; called by muse, mutect2, varscan2
- HNRNPC | c.432T>A p.P144= (on ENST00000420743; = p.P131= on NM_004500.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 59/182 reads (32%) | catalogued as rs1422550385; called by muse, mutect2, varscan2
- KIAA2026 | c.2961A>G p.S987= | Silent (SNP) | VAF 49/134 reads (37%) | catalogued as rs923917662; called by muse, mutect2, varscan2
- MDFIC | c.36C>G p.P12= | Silent (SNP) | VAF 16/77 reads (21%) | catalogued as rs1205566480; called by muse, mutect2, varscan2
- OTUD6A | c.636C>T p.R212= | Silent (SNP) | VAF 58/175 reads (33%) | called by muse, mutect2, varscan2
- PABPC5 | c.9C>T p.S3= | Silent (SNP) | VAF 17/51 reads (33%) | catalogued as COSV57041561; called by muse, mutect2, varscan2
- PCDHGB1 | c.1683C>T p.P561= | Silent (SNP) | VAF 106/314 reads (34%) | catalogued as rs548781270; called by muse, mutect2, varscan2
- SAMD11 | c.421C>A p.R141= | Silent (SNP) | VAF 31/94 reads (33%) | catalogued as COSV100574700; called by muse, mutect2, varscan2
- SLC9A3 | c.153C>T p.H51= | Silent (SNP) | VAF 54/205 reads (26%) | catalogued as rs756665719; called by muse, mutect2, varscan2
- SPTA1 | c.5715T>A p.A1905= | Silent (SNP) | VAF 88/500 reads (18%) | called by muse, mutect2, varscan2
- TTLL8 | c.1899G>A p.R633= | Silent (SNP) | VAF 28/73 reads (38%) | catalogued as rs1341514873; called by muse, mutect2, varscan2
- ZNF236 | c.4650G>A p.S1550= | Silent (SNP) | VAF 50/128 reads (39%) | catalogued as rs752022677, COSV53486408, COSV99469416, COSV99470653; called by muse, mutect2, varscan2
- CSF2RA | c.1125+114G>A | Intron (SNP) | VAF 10/188 reads (5%) | catalogued as rs187465902, COSV100817620; called by muse, mutect2
- LRRFIP1 | c.250-9117G>A | Intron (SNP) | VAF 41/199 reads (21%) | catalogued as rs1056004038, COSV99791385; called by muse, mutect2, varscan2
